Surgical pathology report (de-identified scan), TCGA case TCGA-67-6215, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-6215-01A (Primary Tumor).

[page 1 of 2]
GROSS DESCRIPTION

(Continued)

CGA-67-6215

B. The specimen is submitted fresh as "intralobar node" and consists of multiple soft red black tissue fragments measuring 1.5 x 1.5 x 0.3 cm in aggregate. The specimen is wrapped in tissue paper and submitted in toto, multiple (1).

C. The specimen is submitted fresh as "intralobar node 2" and consists of multiple soft red black tissue fragments measuring 1 x 1 x 0.4 cm in aggregate. The specimen is wrapped in tissue paper and submitted in toto, multiple (1).

D. The specimen is submitted fresh as "superior segmental node" and consists of a red black tissue fragment measuring 0.4 cm in dimension. The specimen is wrapped in tissue paper and submitted, 1 (1).

E. The specimen is submitted fresh as "posterior intralobar node" and consists of a soft red black node measuring 1 cm in greatest dimension. The specimen is bisected, wrapped in tissue paper and submitted, 2 (1).

FINAL DIAGNOSIS

- A. LUNG, RIGHT LOWER LOBE (LOBECTOMY):
- WELL DIFFERENTIATED ADENOCARCINOMA WITH BRONCHO-ALVEOLAR FEATURES.
- TUMOR MEASURES 4 CM IN MAXIMUM DIMENSION AND EXTENDS TO PLEURAL SURFACE WITH PLEURAL PUCKERING, HOWEVER, DOES NOT INVOLVE VISCERAL PLEURA, AND IS 4 CM FROM BRONCHIAL MARGIN.
- UNINVOLVED PULMONARY PARENCHYMA SHOWS SMALL NON-CASEATING GRANULOMATA, NEGATIVE FOR PATHOGENIC ORGANISMS (AFB, GMS), AND MILD EMPHYSEMATOUS CHANGES.
- ALL SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- B. INTRALOBAR NODE: MULTIPLE ANTHRACOTIC LYMPH NODES WITH NON-CASEATING GRANULOMATA SIMILAR TO THAT SEEN IN MEDIASTINOSCOPY ()
NEGATIVE FOR TUMOR.
- C. INTRALOBAR NODE #2: MULTIPLE ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR.
- D. SUPERIOR SEGMENTAL LYMPH NODE: ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR.
- E. POSTERIOR INTRALOBAR NODE: ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR TUMOR.

PATHOLOGIC STAGE: pT2a N0 MX

[page 2 of 2]
SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
SPECIMEN INTEGRITY: INTACT
LATERALITY: RIGHT
TUMOR SITE: LOWER LOBE
TUMOR SIZE: 4 CM
TUMOR FOCALITY: SINGLE
HISTOLOGIC TYPE: ADENOCARCINOMA
HISTOLOGIC GRADE: WELL DIFFERENTIATED
EXTENT OF INVASION: CONFINED TO LUNG
EXTENSION TO PLEURA/OTHER STRUCTURES: NOT INVOLVED
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE NARRATIVE)

MARGINS:

BRONCHIAL: NEGATIVE
PARENCHYMAL: NEGATIVE
VASCULAR: NEGATIVE
OTHER MARGINS (PARIETAL PLEURAL/CHEST WALL, ETC): NEGATIVE
DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 0.15 CM TO PLEURAL MARGIN

NEOADJUVANT TREATMENT EFFECT: N/A

VENOUS INVASION: NOT IDENTIFIED
ARTERIAL (LARGE VESSEL) INVASION: NOT IDENTIFIED
LYMPHATIC INVASION: NOT IDENTIFIED

LYMPH NODE:

N1 - # INVOLVED/# EXAMINED: 0/MULTIPLE
N2 - # INVOLVED/# EXAMINED: 0/MULTIPLE
N3 - # INVOLVED/# EXAMINED: 0/MULTIPLE

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT2a N0 MX

Source: NCI Genomic Data Commons file e826db13-b9e2-4437-8856-c8e3011d4daf (TCGA-67-6215.BDAF595F-AE8E-451F-83D2-3A79EF06B2A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).